CCG case CUPP-B5XO — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bde00c75-5fff-4a83-aad6-2716ab6d3f86

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1954; Vital status: Dead; Days to death: 134 days; Year of death: 2017; Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8070/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 62.6 years (22,879 days); Year of diagnosis: 2017; Method of diagnosis: Surgical Resection; AJCC staging edition: 8th; AJCC clinical T: T0; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T0; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 31; Lymph nodes tested: 40; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R0; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS, postoperative.
2. Recurrence of the lymph node (histology not recorded by GDC). Age at diagnosis: 62.7 years (22,907 days); Year of diagnosis: 2017; Days to diagnosis: 28 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease; Treatment outcome: Partial Response.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 100; ECOG performance status: 0.
- Day 28 (recurrence): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 28 days.
- Follow-up contact recording only the day: day 134.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 171 cm; BMI: 35.9.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 84; Tobacco smoking onset year: 1994; Tobacco smoking quit year: 2016.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Gastric Cancer; Relationship sex at birth: male.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XO-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XO-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
